Somatic mutation profile of tumor specimen TCGA-HC-A632-01A (aliquot TCGA-HC-A632-01A-11D-A29Q-08) from TCGA case TCGA-HC-A632, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 68.2 years (24,916 days).
Specimen TCGA-HC-A632-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ac204f1-3024-4eca-b4af-afea9a8463b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-A632-10A (Blood Derived Normal), aliquot TCGA-HC-A632-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9cfc8af3-460f-4282-85c4-aeef359653c6

The open-access MAF lists 35 somatic variants for this specimen: 24 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 22, Silent 11, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 30/66 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGTR1 | c.322G>A p.V108I | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs373362261; called by muse, mutect2, varscan2
- APC | c.8141G>A p.R2714H | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs747362422, COSV57335133; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ARHGEF2 | c.1366C>T p.P456S (on ENST00000361247 / NM_001162383.2; = p.P428S on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.201); catalogued as COSV58107707; called by muse, mutect2, varscan2
- CCDC85A | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1243441011, COSV68152903; called by muse, mutect2, varscan2
- CHI3L2 | c.955C>T p.L319F | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as COSV63874304; called by muse, mutect2, varscan2
- DENND10 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as rs778222300, COSV63857866; called by muse, mutect2, varscan2
- DNAJC28 | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV58721839; called by muse, mutect2, varscan2
- F10 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as rs138587138; called by muse, mutect2, varscan2
- FAHD2A | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as rs373739961; called by muse, mutect2, varscan2
- GCNT4 | c.880dup p.H294Pfs*2 | Frame Shift Ins (INS) | VAF 12/56 reads (21%) | catalogued as rs768450027; called by mutect2, varscan2
- GGA1 | c.1774A>G p.I592V | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as rs777327586, COSV57330658; called by muse, mutect2
- IL17A | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs756965539, COSV60684959, COSV60685207; called by muse, mutect2, varscan2
- LRP1B | c.13722C>A p.N4574K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV67242610; called by muse, mutect2, varscan2
- LTBR | c.403T>G p.W135G | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV57439316; called by muse, mutect2, varscan2
- OR4A16 | c.929G>A p.R310K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.013); catalogued as COSV100125111, COSV59043906; called by muse, mutect2, varscan2
- PARP1 | c.2332C>T p.L778F | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64691141; called by muse, mutect2, varscan2
- PCDHB7 | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 52/125 reads (42%) | catalogued as COSV50754021, COSV50784549; called by muse, mutect2, varscan2
- PLCH1 | c.4925C>T p.T1642M (on ENST00000340059 / NM_001130960.2; = p.T1634M on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as rs200586305; called by muse, mutect2, varscan2
- PLEC | c.9116G>A p.R3039Q (on ENST00000322810 / NM_201380.4; = p.R2929Q on NM_000445.5) | Missense Mutation (SNP) | VAF 78/132 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.121); catalogued as rs782819280, COSV59649930; called by muse, mutect2, varscan2
- RUFY3 | c.763G>T p.G255C | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV56913947, COSV56914997; called by muse, mutect2, varscan2
- TBCD | c.1549A>G p.N517D | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62803147; called by muse, mutect2, varscan2
- UBAP2 | c.2764C>T p.P922S | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1023473884, COSV54290814; called by muse, mutect2, varscan2
- ZNF827 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV101061769, COSV65229017; called by muse, mutect2, varscan2
- CELSR2 | c.3756C>T p.S1252= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs768473589, COSV54774776; called by muse, mutect2, varscan2
- CFH | c.1140G>A p.S380= | Silent (SNP) | VAF 45/120 reads (38%) | catalogued as rs1273044132, COSV62777808; called by muse, mutect2, varscan2
- DDX4 | c.1524G>A p.V508= | Silent (SNP) | VAF 27/130 reads (21%) | catalogued as COSV61755790; called by muse, mutect2, varscan2
- GCNT2 | c.450T>A p.A150= | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as COSV65457724; called by muse, mutect2, varscan2
- MAB21L4 | c.1083C>T p.R361= (on ENST00000388934 / NM_001085437.3; = p.R193= on NM_024861.4) | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs768517234, COSV56743848; called by muse, mutect2, varscan2
- OPRL1 | c.1065C>T p.D355= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as rs367711919; called by muse, mutect2, varscan2
- RAB33B | c.405T>C p.H135= | Silent (SNP) | VAF 55/135 reads (41%) | catalogued as COSV59777646; called by muse, mutect2, varscan2
- TEX37 | c.114G>A p.P38= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs772549037, COSV57556158; called by muse, mutect2
- UBR4 | c.15414C>A p.A5138= | Silent (SNP) | VAF 79/254 reads (31%) | catalogued as COSV64392881; called by muse, mutect2, varscan2
- USP15 | c.1125A>G p.G375= (on ENST00000280377 / NM_001351159.2; = p.G346= on NM_006313.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV54794703; called by muse, mutect2, varscan2
- XG | c.399C>T p.G133= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV66985837; called by muse, mutect2
